Somatic mutation profile of tumor specimen MP2PRT-PAPXKS-TMP1-A (aliquot MP2PRT-PAPXKS-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPXKS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,254 days).
Specimen MP2PRT-PAPXKS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf716f00-4d92-47cc-91d0-22253f750fea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXKS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXKS-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64bdb3eb-916a-4f83-aae3-0b057906b4e8

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP7D1 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs1396822708; called by mutect2, varscan2
- SCRN1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs531406641, COSV54130775; called by muse, mutect2, varscan2
- VASH1 | c.165C>G p.D55E | Missense Mutation (SNP) | VAF 249/578 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.857); catalogued as COSV51335959; called by muse, mutect2, varscan2
- ZBTB7A | c.522dup p.A175Rfs*19 | Frame Shift Ins (INS) | VAF 161/654 reads (25%) | catalogued as rs749935719; called by mutect2, pindel, varscan2
- ATP2A1 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 116/388 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- DMGDH | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 141/643 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- IZUMO3 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.98); called by muse, mutect2, varscan2
- SRRM2 | c.3622_3623insG p.T1208Sfs*20 | Frame Shift Ins (INS) | VAF 81/324 reads (25%) | called by mutect2, pindel, varscan2
- BCL2 | c.609C>T p.G203= | Silent (SNP) | VAF 72/384 reads (19%) | called by muse, mutect2, varscan2
- LMAN2 | c.363C>T p.H121= | Silent (SNP) | VAF 88/344 reads (26%) | catalogued as rs767510847, COSV57425459; called by muse, varscan2
- NSUN4 | c.825G>A p.R275= | Silent (SNP) | VAF 58/240 reads (24%) | catalogued as rs767237606; called by muse, mutect2, varscan2
- TRPC7 | c.1065C>T p.V355= | Silent (SNP) | VAF 97/367 reads (26%) | called by muse, mutect2, varscan2
- ZMYM2 | c.690C>T p.N230= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as rs753289816; called by muse, mutect2, varscan2
